Gene-level copy-number profile of tumor specimen ALCH-B48S-TTP1-A from ALCHEMIST case ALCH-B48S, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.9 years (22,238 days).
Specimen ALCH-B48S-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9bf59b6b-2e18-440a-a22c-93921c17a185.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B48S-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,724 have no estimate.
https://portal.gdc.cancer.gov/files/3b992a91-e95a-4940-98b2-06df7b812744

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 48; copy number 1: 7,793; copy number 2: 28,248; copy number 3: 17,209; copy number 4: 5,268; copy number 5: 328; copy number 6: 4; copy number 9: 1.

Homozygous deletions (total copy number 0; autosomes only): 47 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,929,994–143,930,382, 1 gene (within-gene range 0–1): RPL22P5.
- chr2:218,382,029–218,399,219, 2 genes: SLC11A1, AC021016.2.
- chr3:48,633,636–48,669,174, 4 genes (within-gene range 0–1): MIR6824, CELSR3, MIR4793, LINC02585.
- chr3:50,287,732–50,328,251, 6 genes (within-gene range 0–1): IFRD2, HYAL3, NAA80, HYAL1, HYAL2, TUSC2.
- chr3:156,175,852–156,176,911, 1 gene (within-gene range 0–4): AC091607.1.
- chr8:7,778,591–7,841,242, 5 genes: PRR23D2, DEFB107A, DEFB105A, DEFB106A, DEFB104A.
- chr8:7,881,392–7,896,716, 3 genes: DEFB103A, HSPD1P2, DEFB4A.
- chr8:7,934,412–7,938,770, 1 gene (within-gene range 0–1): DEFB108A.
- chr8:8,019,429–8,040,953, 3 genes: FAM90A24P, FAM90A12P, OR7E96P.
- chr8:12,064,389–12,177,550, 10 genes: DEFB130B, RNA5SP253, DEFB108D, ZNF705D, FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D, FAM90A2P.
- chr10:14,959,388–14,988,050, 2 genes: MEIG1, OR7E110P.
- chr12:11,351,823–11,395,566, 1 gene (within-gene range 0–2): PRB1.
- chr15:23,430,839–23,435,212, 1 gene: HERC2P6.
- chr17:45,506,741–45,563,230, 7 genes: LRRC37A4P, Metazoa_SRP, AC091132.3, AC091132.1, AC091132.4, AC091132.5, RDM1P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 333 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:130,048,143–130,055,920, 1 gene, copy number 5: AC083906.4.
- chr7:30,027,404–30,134,714, 4 genes, copy number 5: PLEKHA8, AC007285.1, AC007036.4, AC007036.5.
- chr7:74,773,962–74,789,376, 1 gene, copy number 5: NCF1.
- chr9:12,134–7,961,224, 138 genes, copy number 5 (broad region; genes not listed).
- chr9:12,685,439–23,438,700, 163 genes, copy number 5 (broad region; genes not listed).
- chr9:64,765,054–64,765,535, 1 gene, copy number 9: IGKV1OR-2.
- chr16:32,103,245–32,188,107, 1 gene, copy number 5 (within-gene range 3–5): HERC2P4.
- chr16:32,126,432–32,279,115, 10 genes, copy number 5: AC133485.7, AC133485.6, AC133485.5, AC133485.4, ABHD17AP8, AC133485.1, AC133485.3, TP53TG3D, AC133485.2, AC140878.1.
- chr17:18,476,737–18,551,705, 5 genes, copy number 5–6 (within-gene range 2–6): LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.
- chr21:43,107,942–43,168,646, 1 gene, copy number 5 (within-gene range 3–5): AP001631.2.
- chr21:43,159,066–43,172,805, 2 genes, copy number 5: AP001631.1, CRYAA.
- chr21:44,579,455–44,580,604, 1 gene, copy number 5 (within-gene range 3–5): KRTAP10-5.
- chr21:44,612,079–44,612,954, 1 gene, copy number 5 (within-gene range 3–5): KRTAP10-8.
- chr21:44,646,414–44,666,927, 4 genes, copy number 5 (within-gene range 3–5): KRTAP10-11, KRTAP12-4, KRTAP12-3, KRTAP12-2.

Autosomal genes at a single copy (total copy number 1): 7,780. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
